Somatic mutation profile of tumor specimen MP2PRT-PARSHU-TMP1-A (aliquot MP2PRT-PARSHU-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARSHU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,290 days).
Specimen MP2PRT-PARSHU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb865a34-ff99-409d-b44d-082ed7ce86b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARSHU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARSHU-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e914e36e-1687-41ab-8726-ff3cae056010

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Nonsense Mutation 4, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BORCS6 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 45/1337 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV66505356; called by muse, mutect2
- FHAD1 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 119/514 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs747370305; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 288/1076 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs76869428; called by mutect2, varscan2
- IRS4 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 315/318 reads (99%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.353); catalogued as rs766893547; called by muse, mutect2, varscan2
- NCOR2 | c.3656C>T p.S1219L | Missense Mutation (SNP) | VAF 149/647 reads (23%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.458); catalogued as rs909322345; called by muse, mutect2, varscan2
- SYNE1 | c.21715C>T p.Q7239* (on ENST00000367255 / NM_182961.4; = p.Q7168* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 131/483 reads (27%) | catalogued as COSV55044875; called by muse, mutect2, varscan2
- TTC8 | c.1178A>T p.D393V (on ENST00000338104 / NM_001288781.1; = p.D377V on NM_144596.4) | Missense Mutation (SNP) | VAF 294/619 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57625844; called by muse, mutect2, varscan2
- USP28 | c.2044C>T p.Q682* | Nonsense Mutation (SNP) | VAF 32/402 reads (8%) | catalogued as COSV50208915; called by muse, mutect2
- ZKSCAN5 | c.1802G>A p.G601D | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1417263879; called by muse, mutect2
- ADAMTS8 | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 214/550 reads (39%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, varscan2
- BRIX1 | c.477G>C p.L159F | Missense Mutation (SNP) | VAF 136/548 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- C11orf53 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 13/413 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); called by muse, mutect2
- CCDC168 | c.8788T>A p.S2930T | Missense Mutation (SNP) | VAF 238/445 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- CCT6B | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 98/438 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- CNTNAP3 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 52/380 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- DHCR7 | c.677A>T p.N226I | Missense Mutation (SNP) | VAF 259/563 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- H2BC21 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 183/535 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HIVEP2 | c.5770C>T p.Q1924* | Nonsense Mutation (SNP) | VAF 55/618 reads (9%) | called by muse, mutect2
- KIF21A | c.1684C>G p.L562V | Missense Mutation (SNP) | VAF 101/559 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TAS1R1 | c.2304C>G p.F768L | Missense Mutation (SNP) | VAF 17/540 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- THSD1 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 101/456 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- USH2A | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 123/288 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF24 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 162/593 reads (27%) | called by muse, varscan2
- CDH10 | c.1197G>A p.V399= | Silent (SNP) | VAF 188/435 reads (43%) | called by muse, mutect2, varscan2
- FOXF1 | c.390C>T p.F130= | Silent (SNP) | VAF 173/679 reads (25%) | called by muse, mutect2, varscan2
- P2RY12 | c.561T>C p.H187= | Silent (SNP) | VAF 142/302 reads (47%) | catalogued as rs923308300, CM150856; called by muse, mutect2, varscan2
- PAK5 | c.753G>A p.A251= | Silent (SNP) | VAF 197/402 reads (49%) | catalogued as rs780571800, COSV62035905; called by muse, mutect2, varscan2
- POU3F4 | c.156C>T p.P52= | Silent (SNP) | VAF 325/338 reads (96%) | catalogued as rs1443674164, COSV64540578; called by muse, mutect2, varscan2
- SP5 | c.243G>T p.S81= | Silent (SNP) | VAF 460/955 reads (48%) | catalogued as rs1433762609; called by muse, mutect2, varscan2
- SYNE1 | c.21630C>T p.T7210= (on ENST00000367255 / NM_182961.4; = p.T7139= on NM_033071.3) | Silent (SNP) | VAF 108/451 reads (24%) | called by muse, mutect2, varscan2
- ZBED4 | c.2916C>T p.F972= | Silent (SNP) | VAF 136/558 reads (24%) | catalogued as rs557025150; called by muse, mutect2, varscan2
- ZNF98 | c.183G>A p.L61= | Silent (SNP) | VAF 30/692 reads (4%) | called by muse, mutect2
- NHSL2 | chrX:72143313 G>A | 3'Flank (SNP) | VAF 31/260 reads (12%) | catalogued as rs1212286903; called by muse, mutect2, varscan2
